Gene-level copy-number profile of tumor specimen TCGA-34-2600-01A from TCGA case TCGA-34-2600, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.9 years (28,072 days).
Specimen TCGA-34-2600-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b985fa26-fc29-4a61-8051-fcd9d723e29e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-2600-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e9aa7d4-6d0b-46bf-b927-0a060bc4283e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,237; copy number 2: 22,006; copy number 3: 22,353; copy number 4: 10,193; copy number 5: 829; copy number 6: 1,330; copy number 7: 259; copy number 8: 1,473; copy number 9: 53; copy number 10: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-2600-01A-01D-0844-01): tumor purity 0.86, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,807 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,421,979–46,413,848, 439 genes, copy number 6 (broad region; genes not listed).
- chr2:113,107,214–113,134,016, 1 gene, copy number 5 (within-gene range 3–5): IL1RN.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 6–8 (broad region; genes not listed).
- chr9:32,293,558–43,045,120, 376 genes, copy number 5–10 (broad region; genes not listed).
- chr18:56,597,209–80,247,514, 361 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–38,383,179, 823 genes, copy number 6–7 (broad region; genes not listed).
- chr20:50,888,916–51,023,107, 7 genes, copy number 9: ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1.

Autosomal genes at a single copy (total copy number 1): 1,059. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
